Somatic mutation profile of tumor specimen MMRF_2758_1_BM_CD138pos (aliquot MMRF_2758_1_BM_CD138pos_T1_KHS5U_L15081) from MMRF case MMRF_2758, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.9 years (16,047 days).
Specimen MMRF_2758_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f90f612e-e6aa-4ff4-be65-818475dfbef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2758_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2758_1_PB_WBC_C2_KHS5U_L15095; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27bcb468-045e-4dbb-9b4d-9c93636b2c1e

The open-access MAF lists 84 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 22, Missense Mutation 22, Intron 11, Silent 9, 5'UTR 8, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 2, 3'Flank 2, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CERS5 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs1402501914; called by muse, mutect2, varscan2
- IGHV2-70 | c.317T>G p.M106R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs781447645; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGLL5 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs537757846, COSV73250110; called by muse, mutect2
- KCTD10 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV57328080; called by muse, mutect2, varscan2
- KRT1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs1268526292; called by muse, varscan2
- NEK5 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200564973; called by muse, mutect2, varscan2
- OR5A1 | c.266_268del p.F89del | In Frame Del (DEL) | VAF 63/254 reads (25%) | catalogued as rs1367795210; called by pindel, varscan2
- SLC28A1 | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs770895559; called by muse, mutect2, varscan2
- ANKRD37 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- DNAJB13 | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- DROSHA | c.1835del p.L612Rfs*9 | Frame Shift Del (DEL) | VAF 18/208 reads (9%) | called by mutect2, pindel
- DTD1 | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EPG5 | c.875_877del p.E292_L293delinsV | In Frame Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel, varscan2
- GALNT8 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2
- GON4L | c.3743A>T p.K1248I | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IFT140 | c.1581G>C p.L527F | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGHV2-70 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, varscan2
- INHBB | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLST8 | c.863-3C>T | Splice Region (SNP) | VAF 82/208 reads (39%) | called by muse, mutect2, varscan2
- PABPC5 | c.175dup p.L59Pfs*7 | Frame Shift Ins (INS) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- PGLYRP4 | c.1064T>C p.L355S | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- PICALM | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SMARCA5 | c.2609G>A p.R870K | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SOX4 | c.1075del p.R359Afs*50 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- STAT3 | c.1683C>G p.F561L | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZKSCAN5 | c.1448A>G p.D483G | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF432 | c.756A>C p.Q252H | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF559 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ZNF567 | c.1721C>T p.S574L (on ENST00000536254 / NM_001322913.1; = p.S543L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- COL11A1 | c.3108A>G p.G1036= | Silent (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- DDX25 | c.723T>C p.I241= | Silent (SNP) | VAF 123/223 reads (55%) | called by muse, mutect2, varscan2
- DND1 | c.159G>A p.P53= | Silent (SNP) | VAF 105/199 reads (53%) | called by muse, mutect2, varscan2
- FNDC1 | c.4299G>A p.P1433= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1314688437; called by muse, mutect2, varscan2
- GASK1B | c.570C>T p.A190= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as rs575833676, COSV99647541; called by muse, mutect2, varscan2
- GUCY1B1 | c.1383T>C p.T461= | Silent (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- OR4C11 | c.906C>A p.G302= | Silent (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- OR5AR1 | c.663C>T p.I221= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV57254883; called by muse, mutect2
- PUS10 | c.1053A>C p.G351= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- ATXN2 | c.*378A>G | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, varscan2
- AZU1 | chr19:825184 G>T | 5'Flank (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- BLVRA | c.254+158A>T | Intron (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- BTG1 | c.-94T>A | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- CABP7 | c.*2093G>A | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- CD177P1 | n.809T>C | RNA (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- CDH10 | c.*286C>T | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- DDR1 | c.1100-95G>A | Intron (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- DMXL2 | c.-190C>T | 5'UTR (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- EGR1 | c.-15G>A | 5'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs1401034545; called by muse, mutect2, varscan2
- GAREM1 | c.*355T>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1380227314, COSV52514017; called by muse, varscan2
- GRIA2 | c.-134T>G | 5'UTR (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- GRTP1 | c.182-129C>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- HMCN2 | c.*241G>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- HNRNPC | chr14:21210217 G>A | 3'Flank (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- HOXC6 | c.*780del | 3'UTR (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- ITGA4 | c.556+645C>T | Intron (SNP) | VAF 87/225 reads (39%) | called by muse, mutect2, varscan2
- JDP2 | chr14:75473787 T>C | 3'Flank (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- KIAA1191 | c.*500T>C | 3'UTR (SNP) | VAF 41/160 reads (26%) | called by muse, varscan2
- KIAA1191 | c.*419T>C | 3'UTR (SNP) | VAF 40/168 reads (24%) | called by muse, varscan2
- LINGO2 | c.*418A>G | 3'UTR (SNP) | VAF 6/100 reads (6%) | catalogued as rs1346028545; called by muse, mutect2
- MBP | c.576+2945T>A | Intron (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- MROH2B | c.-298del | 5'UTR (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- MTO1 | c.*651T>C | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- NECAP1 | c.*638A>G | 3'UTR (SNP) | VAF 8/41 reads (20%) | catalogued as rs867461640; called by muse, mutect2, varscan2
- NOSTRIN | c.964+299A>C | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- PDE5A | c.*1898A>G | 3'UTR (SNP) | VAF 13/35 reads (37%) | catalogued as rs201597913; called by muse, mutect2, varscan2
- PHKG2 | c.*272G>A | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- POU2AF1 | c.-98A>G | 5'UTR (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- PPDPFL | c.*663A>G | 3'UTR (SNP) | VAF 108/339 reads (32%) | called by muse, mutect2, varscan2
- PPP2R3A | c.*1717A>C | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.-224C>T | 5'UTR (SNP) | VAF 30/144 reads (21%) | catalogued as rs1367886607; called by muse, mutect2, varscan2
- RBL1 | c.*1447A>T | 3'UTR (SNP) | VAF 46/201 reads (23%) | called by muse, mutect2, varscan2
- RCHY1 | c.*3386del | 3'UTR (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- RPTN | c.*110C>T | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- SLC22A18 | c.-4C>T | 5'UTR (SNP) | VAF 29/101 reads (29%) | catalogued as COSV100388638; called by muse, mutect2
- SLITRK5 | c.*415C>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- SPART | c.-3+4609A>G | Intron (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- SYT7 | c.215+5178G>A | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- SYTL2 | c.1460-3378G>T | Intron (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- TTC14 | c.1290+54C>T | Intron (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- TTYH1 | c.1315-34C>A | Intron (SNP) | VAF 25/372 reads (7%) | called by muse, mutect2
- WDR47 | c.*662A>G | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- ZNF655 | c.*424A>T | 3'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs1049477532; called by muse, mutect2, varscan2
- ZNF780B | c.*575T>C | 3'UTR (SNP) | VAF 103/234 reads (44%) | called by muse, mutect2, varscan2
